Somatic mutation profile of tumor specimen TARGET-20-PARGDB-03A (aliquot TARGET-20-PARGDB-03A-01D) from TARGET case TARGET-20-PARGDB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.8 years (6,149 days).
Specimen TARGET-20-PARGDB-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abdbde93-2d8b-4023-aa2d-55d4127ce05a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARGDB-14A (Bone Marrow Normal), aliquot TARGET-20-PARGDB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a52eff3-350a-46ab-9ec8-2c9bf9f54591

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 34/163 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GATA2 | c.1051A>T p.N351Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62004045; called by muse, mutect2, varscan2
- WT1 | c.1092dup p.T365Dfs*8 | Frame Shift Ins (INS) | VAF 34/138 reads (25%) | catalogued as COSV100189314, COSV60066218, COSV60070964, COSV60071625, COSV60074596, COSV60085914, COSV60087225; called by pindel, varscan2
